Somatic mutation profile of tumor specimen ALCH-B1U7-TTP1-A (aliquot ALCH-B1U7-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1U7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.4 years (22,044 days).
Specimen ALCH-B1U7-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e0a91e8-7691-4ad4-b6b0-3314bbe7a8b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1U7-NB1-A (Blood Derived Normal), aliquot ALCH-B1U7-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc750408-99b3-4a20-be4e-f43eaa84448b

The open-access MAF lists 166 somatic variants for this specimen: 118 protein-altering or splice-affecting, 35 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 35, RNA 5, Nonsense Mutation 5, Splice Site 3, Intron 3, Frame Shift Del 3, 3'UTR 3, 5'UTR 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 24/260 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 8/80 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCA13 | c.12799del p.E4267Rfs*32 | Frame Shift Del (DEL) | VAF 5/62 reads (8%) | catalogued as COSV101291485, COSV68946127; called by mutect2, pindel
- ADARB1 | c.1777G>A p.G593R (on ENST00000360697 / NM_001346687.2; = p.G553R on NM_001112.4) | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.83); catalogued as rs183042891; called by muse, mutect2, varscan2
- ARHGAP12 | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs755977039, COSV60963576; called by muse, mutect2, varscan2
- ASPM | c.3422G>T p.G1141V | Missense Mutation (SNP) | VAF 56/357 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99659389; called by muse, mutect2, varscan2
- BAHD1 | c.925G>T p.G309W | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs1164351248; called by muse, mutect2, varscan2
- CCDC50 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV101165338, COSV101165375; called by mutect2, varscan2
- CD33 | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51801870; called by muse, mutect2, varscan2
- CLCN7 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs537057233; ClinVar: uncertain significance; called by mutect2, varscan2
- CPT1C | c.1669C>T p.R557* | Nonsense Mutation (SNP) | VAF 14/249 reads (6%) | catalogued as rs748659009, COSV54920582; called by muse, mutect2
- CRISP1 | c.612C>A p.D204E | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as COSV59993709; called by muse, mutect2, varscan2
- CYP4F3 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs545365201; called by muse, mutect2, varscan2
- DCC | c.3166C>T p.R1056C | Missense Mutation (SNP) | VAF 21/310 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV71428912, COSV71441321; called by muse, mutect2
- DSG3 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 45/397 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs755487489, COSV57125339; called by muse, mutect2, varscan2
- FAM193A | c.742C>G p.P248A | Missense Mutation (SNP) | VAF 27/391 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs928706053; called by muse, mutect2
- FER1L6 | c.144G>T p.L48F | Missense Mutation (SNP) | VAF 26/279 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV101206143; called by muse, mutect2
- FLG | c.8735C>A p.S2912Y | Missense Mutation (SNP) | VAF 36/798 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV64240480; called by muse, mutect2
- FMNL1 | c.2945C>T p.S982F | Missense Mutation (SNP) | VAF 9/222 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1381177347; called by muse, mutect2
- GCN1 | c.4165G>T p.D1389Y | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100324814; called by muse, mutect2
- GUCY2D | c.2387C>A p.P796H | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54699006; called by muse, mutect2
- HOXA5 | c.485C>A p.A162E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.049); catalogued as COSV56074162; called by muse, mutect2, varscan2
- HTT | c.5977G>T p.V1993L | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as rs1316757421; called by muse, mutect2
- IZUMO1R | c.670C>A p.P224T (on ENST00000440961; = p.P231T on NM_001199206.3) | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV60623612; called by muse, mutect2, varscan2
- KSR1 | c.1610C>T p.A537V (on ENST00000644974 / NM_001367810.1; = p.A422V on NM_014238.2) | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs770696646; called by muse, mutect2
- NCAPH | c.940C>G p.Q314E | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.91); PolyPhen benign (0.253); catalogued as COSV53637672, COSV99545659; called by muse, mutect2
- NR0B1 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.521); catalogued as rs1408937544, COSV66764687; called by muse, mutect2
- NTM | c.746C>A p.P249H | Missense Mutation (SNP) | VAF 17/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66191183; called by muse, mutect2
- OR10H3 | c.334C>A p.H112N | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.881); catalogued as rs1427576996; called by muse, mutect2
- OR2M5 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV63546265, COSV63546884; called by muse, mutect2, varscan2
- OR5V1 | c.235C>G p.P79A | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65830373; called by muse, mutect2, varscan2
- PAX8 | c.1069G>A p.G357S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs1396590694; called by muse, mutect2, varscan2
- PCDHA10 | c.1619G>T p.G540V | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs375722457; called by muse, mutect2
- PKHD1L1 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1306230488; called by muse, mutect2
- RFESD | c.166C>A p.R56S | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV99174175; called by muse, mutect2, varscan2
- RP1L1 | c.4110G>T p.E1370D | Missense Mutation (SNP) | VAF 82/619 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.678); catalogued as COSV66758741; called by muse, mutect2, varscan2
- SALL4 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53855163; called by muse, mutect2
- SLC9A2 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV52133201; called by muse, mutect2, varscan2
- SYNE1 | c.68-1G>T p.X23_splice | Splice Site (SNP) | VAF 26/254 reads (10%) | catalogued as rs1440276153, COSV55065296; called by muse, mutect2
- TBC1D8B | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV99344044; called by muse, mutect2, varscan2
- TPM2 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as CM1312396; called by muse, mutect2
- TUBA3C | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); catalogued as COSV67139222; called by muse, mutect2, varscan2
- WDR45B | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 36/476 reads (8%) | catalogued as rs1391857942, COSV101124474; called by muse, mutect2
- ZDHHC13 | c.754A>T p.T252S | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.328); catalogued as COSV101239874; called by muse, varscan2
- ZFYVE27 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1481321102, COSV61747238; called by muse, mutect2, varscan2
- ZNF331 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 23/196 reads (12%) | catalogued as COSV53475721; called by muse, mutect2, varscan2
- ZNF530 | c.1726G>T p.E576* | Nonsense Mutation (SNP) | VAF 24/142 reads (17%) | catalogued as COSV60531547; called by muse, mutect2, varscan2
- ZNF804A | c.2863C>A p.P955T | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as COSV100167892; called by muse, mutect2, varscan2
- ACTN2 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ADAMTS9 | c.2162A>T p.Q721L | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- ADCK5 | c.1032C>G p.I344M | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- ANKRD31 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ANPEP | c.1690G>C p.E564Q | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- C2CD3 | c.1039G>T p.D347Y | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.564); called by muse, mutect2
- CACNA1B | c.1355G>T p.S452I | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2
- CCDC102B | c.1408C>G p.Q470E | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCR8 | c.129C>G p.C43W | Missense Mutation (SNP) | VAF 28/317 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- CDH10 | c.1757T>A p.V586E | Missense Mutation (SNP) | VAF 55/438 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH6 | c.524-2A>T p.X175_splice | Splice Site (SNP) | VAF 37/321 reads (12%) | called by muse, mutect2, varscan2
- CEP97 | c.2183G>T p.S728I | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2
- CLPB | c.1420G>A p.G474S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNTN5 | c.590T>C p.F197S | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, varscan2
- CNTN5 | c.2413del p.E805Kfs*22 | Frame Shift Del (DEL) | VAF 21/158 reads (13%) | called by mutect2, pindel, varscan2
- COL22A1 | c.1287C>A p.H429Q | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- COPB1 | c.1456A>T p.I486F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- CPED1 | c.663G>T p.M221I | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- CTNNA3 | c.1840T>G p.Y614D | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CTNND2 | c.2925G>A p.M975I | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, mutect2
- DCTN4 | c.1072-2A>T p.X358_splice | Splice Site (SNP) | VAF 12/139 reads (9%) | called by muse, mutect2
- DDX41 | c.514del p.E172Rfs*15 | Frame Shift Del (DEL) | VAF 27/194 reads (14%) | called by mutect2, pindel, varscan2
- DNAJC3 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- DOCK2 | c.3860A>T p.Y1287F | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); called by muse, mutect2
- DZIP1L | c.2203G>T p.D735Y | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- EFHC2 | c.491C>T p.T164I | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- FAM135B | c.4066G>T p.A1356S | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- FAM227B | c.867G>T p.W289C | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FRYL | c.2020C>T p.P674S | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HAS1 | c.445C>A p.R149S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HEATR6 | c.3064G>T p.A1022S | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2
- IFTAP | c.648A>T p.L216F | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- KRTAP19-1 | c.146G>C p.G49A | Missense Mutation (SNP) | VAF 46/357 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- LLCFC1 | c.377G>T p.S126I (on ENST00000458732; = p.S95I on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- MAP1B | c.3581C>A p.A1194D | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MXRA5 | c.6817C>A p.P2273T | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NFASC | c.540G>T p.M180I (on ENST00000339876 / NM_001378329.1; = p.M174I on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NIBAN1 | c.1391G>T p.G464V | Missense Mutation (SNP) | VAF 41/292 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- NPY1R | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR10H4 | c.761A>T p.Y254F | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.984); called by muse, mutect2
- OR10J3 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- OR4C46 | c.683T>C p.L228S | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.023); called by muse, mutect2
- OR5I1 | c.319T>G p.C107G | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.986); called by muse, varscan2
- OR5K3 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OSBPL6 | c.2677C>A p.H893N | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2
- PARG | c.728C>A p.P243H | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.319); called by muse, mutect2
- PCDHA1 | c.1385T>A p.V462E | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PCDHB1 | c.1528G>T p.G510C | Missense Mutation (SNP) | VAF 40/279 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- PCDHGA3 | c.1474A>T p.T492S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PKHD1 | c.4606G>T p.V1536F | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- PRKG1 | c.1906G>C p.G636R | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PROX1 | c.1954G>T p.E652* | Nonsense Mutation (SNP) | VAF 21/244 reads (9%) | called by muse, mutect2
- PTCHD4 | c.956C>A p.T319N | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RASGRF2 | c.2218G>T p.V740L | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- RECQL5 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RP1 | c.5744G>T p.G1915V | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RYR2 | c.10168C>A p.P3390T | Missense Mutation (SNP) | VAF 43/259 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- SCML2 | c.2080C>T p.L694F | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SEMA3A | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SETD5 | c.2348G>T p.R783L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC35F3 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- SLC9A7 | c.1513G>T p.A505S | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.034); called by muse, mutect2
- SOX11 | c.461C>G p.A154G | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TARS1 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.199); called by muse, mutect2
- TBC1D28 | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- USP48 | c.2098A>G p.R700G | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.071); called by muse, mutect2
- VPS13A | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2
- ZNF548 | c.1041G>T p.R347S | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF658 | c.89G>T p.R30M | Missense Mutation (SNP) | VAF 39/370 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); called by muse, mutect2
- ZNF658 | c.237A>T p.P79= | Splice Region (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2
- ACOD1 | c.753A>T p.P251= | Silent (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- ADCY7 | c.2910C>T p.A970= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as rs766125018; called by muse, mutect2
- ADCY8 | c.2313C>T p.L771= | Silent (SNP) | VAF 18/392 reads (5%) | called by muse, mutect2
- BBS2 | c.156C>G p.V52= | Silent (SNP) | VAF 35/223 reads (16%) | called by muse, mutect2, varscan2
- CACNA1E | c.4383G>T p.P1461= | Silent (SNP) | VAF 26/227 reads (11%) | catalogued as COSV62387110; called by muse, mutect2, varscan2
- CAPN8 | c.852C>G p.L284= | Silent (SNP) | VAF 12/230 reads (5%) | catalogued as rs1272825031; called by muse, mutect2
- CST9L | c.165C>A p.V55= | Silent (SNP) | VAF 39/305 reads (13%) | called by muse, mutect2, varscan2
- CYP4F3 | c.1518G>T p.L506= | Silent (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- DHCR7 | c.1326C>T p.H442= | Silent (SNP) | VAF 15/177 reads (8%) | called by muse, mutect2
- EDEM3 | c.642A>G p.P214= | Silent (SNP) | VAF 56/256 reads (22%) | catalogued as rs778771129; called by muse, mutect2, varscan2
- EPG5 | c.1086G>C p.V362= | Silent (SNP) | VAF 30/316 reads (9%) | catalogued as COSV99956234; called by muse, mutect2
- EPHA6 | c.3108C>A p.T1036= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs1360644801, COSV67584859; called by muse, mutect2, varscan2
- FER1L5 | c.2703G>A p.E901= (on ENST00000623019; = p.E906= on NM_001293083.2) | Silent (SNP) | VAF 16/135 reads (12%) | catalogued as rs746081215, COSV101208788; called by muse, mutect2, varscan2
- FLG | c.8736C>A p.S2912= | Silent (SNP) | VAF 36/803 reads (4%) | called by muse, mutect2
- GALNTL6 | c.735C>T p.L245= | Silent (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- IFNA16 | c.261C>A p.T87= | Silent (SNP) | VAF 14/186 reads (8%) | catalogued as rs551146831; called by muse, mutect2
- IGFBP5 | c.414G>A p.R138= | Silent (SNP) | VAF 27/206 reads (13%) | catalogued as COSV52083396; called by muse, mutect2, varscan2
- JPH4 | c.1527A>T p.L509= | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- MAGEB3 | c.630G>C p.V210= | Silent (SNP) | VAF 24/236 reads (10%) | catalogued as COSV100854779; called by muse, mutect2, varscan2
- MSX1 | c.543C>A p.T181= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs147849679; called by muse, mutect2, varscan2
- MUC5B | c.5973C>A p.T1991= | Silent (SNP) | VAF 22/261 reads (8%) | catalogued as rs761679796; called by muse, mutect2
- MYLIP | c.1161C>T p.C387= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as rs565194272; called by muse, mutect2, varscan2
- MYOM2 | c.777G>T p.V259= | Silent (SNP) | VAF 24/242 reads (10%) | called by muse, mutect2
- NEU3 | c.1113A>G p.K371= | Silent (SNP) | VAF 10/282 reads (4%) | called by muse, mutect2
- NFASC | c.1434C>T p.Y478= (on ENST00000339876 / NM_001378329.1; = p.Y489= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/544 reads (7%) | called by muse, mutect2
- NPAS4 | c.708C>A p.I236= | Silent (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2
- NTM | c.747C>A p.P249= | Silent (SNP) | VAF 17/215 reads (8%) | catalogued as rs1565446707; called by muse, mutect2
- OR1L4 | c.192C>T p.L64= | Silent (SNP) | VAF 16/408 reads (4%) | called by muse, mutect2
- PDZD7 | c.513C>A p.G171= | Silent (SNP) | VAF 11/100 reads (11%) | called by muse, mutect2, varscan2
- PRB1 | c.270C>A p.P90= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV53706399; called by muse, mutect2, varscan2
- RTN1 | c.876T>A p.V292= | Silent (SNP) | VAF 22/222 reads (10%) | called by muse, mutect2
- SCN11A | c.4701T>C p.C1567= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs1369670366; called by muse, mutect2, varscan2
- SLC22A5 | c.45G>A p.G15= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV55372778; called by muse, mutect2, varscan2
- TMEM215 | c.561T>A p.S187= | Silent (SNP) | VAF 27/209 reads (13%) | catalogued as COSV100713288; called by muse, mutect2, varscan2
- WWC2 | c.999C>G p.A333= | Silent (SNP) | VAF 22/194 reads (11%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*1108G>T | 3'UTR (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- CIAO3 | c.162+10A>T | Intron (SNP) | VAF 27/163 reads (17%) | called by muse, mutect2, varscan2
- ESPNP | n.345G>A | RNA (SNP) | VAF 10/102 reads (10%) | catalogued as rs1299118341; called by muse, mutect2
- FAM153CP | n.614A>T | RNA (SNP) | VAF 28/400 reads (7%) | called by muse, mutect2
- FAM205BP | n.2200A>G | RNA (SNP) | VAF 57/328 reads (17%) | catalogued as rs537803122; called by muse, mutect2, varscan2
- GVINP1 | n.3722A>T | RNA (SNP) | VAF 24/180 reads (13%) | called by muse, mutect2, varscan2
- HLA-DQB2 | c.*759C>A | 3'UTR (SNP) | VAF 14/170 reads (8%) | called by muse, mutect2
- IGKV1-12 | c.-6C>A | 5'UTR (SNP) | VAF 42/901 reads (5%) | called by muse, mutect2
- LINC01193 | n.1451A>T | RNA (SNP) | VAF 32/464 reads (7%) | catalogued as rs1475943543; called by muse, mutect2
- PCDHGA3 | c.2425-67388G>T | Intron (SNP) | VAF 37/248 reads (15%) | called by muse, mutect2, varscan2
- PIDD1 | c.1303-26G>T | Intron (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- RAD51D | c.*949A>T | 3'UTR (SNP) | VAF 56/441 reads (13%) | called by muse, mutect2, varscan2
- ZNF257 | c.-14C>A | 5'UTR (SNP) | VAF 16/95 reads (17%) | called by muse, mutect2, varscan2
